Somatic mutation profile of tumor specimen MMRF_2211_1_BM_CD138pos (aliquot MMRF_2211_1_BM_CD138pos_T1_KHS5U_L08813) from MMRF case MMRF_2211, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 45.5 years (16,609 days).
Specimen MMRF_2211_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e691221c-5df3-4bfd-ae0d-7967f1ed3ccd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2211_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2211_1_PB_Whole_C2_KHS5U_L08773; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0e97de7-c1c4-499f-bc10-50db46ae4a4f

The open-access MAF lists 111 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 35, Intron 12, Silent 12, 5'UTR 3, 3'Flank 2, Splice Site 2, Nonsense Mutation 2, RNA 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS7 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs148218299; called by muse, mutect2
- ADGRL3 | c.396A>C p.K132N (on ENST00000506720 / NM_001322402.2; = p.K64N on NM_015236.6) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV72269705; called by muse, mutect2, varscan2
- CACNA1E | c.3812G>A p.R1271H | Missense Mutation (SNP) | VAF 76/148 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62416471; called by muse, mutect2, varscan2
- CHD5 | c.4474C>T p.R1492W | Missense Mutation (SNP) | VAF 49/50 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761795865, COSV52418303; called by muse, mutect2, varscan2
- DDX17 | c.1622A>G p.N541S | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as rs546476409, COSV53246498; called by muse, mutect2, varscan2
- FGFR2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 79/114 reads (69%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as COSV60640640; called by muse, mutect2, varscan2
- FLT4 | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99986244; called by muse, mutect2, varscan2
- GALNT9 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 92/180 reads (51%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.988); catalogued as rs1454884592, COSV61098569; called by muse, mutect2, varscan2
- NUP210 | c.3001G>A p.V1001M | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757686840, COSV54414340; called by muse, mutect2, varscan2
- PLB1 | c.3095T>C p.L1032P | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs1266603483; called by muse, mutect2, varscan2
- PPP1R37 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs1297581592, COSV55526904, COSV99674704; called by muse, mutect2, varscan2
- PRPF19 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57127337; called by muse, mutect2, varscan2
- RIMS4 | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs760125744; called by muse, mutect2, varscan2
- THSD7A | c.1350C>A p.N450K | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as COSV70272876; called by muse, mutect2
- ZNF697 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 105/114 reads (92%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs200668798; called by muse, mutect2, varscan2
- ABI3 | c.946C>A p.L316M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ADCK5 | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ADGRL2 | c.4064T>G p.L1355R (on ENST00000370717 / NM_001366005.1; = p.L1299R on NM_012302.4) | Missense Mutation (SNP) | VAF 207/216 reads (96%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- APOBEC3F | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.243); called by muse, varscan2
- BCL3 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1I | c.398A>C p.K133T | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDC42BPA | c.3338T>A p.L1113H (on ENST00000334218 / NM_001366019.2; = p.L1100H on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDH7 | c.601T>C p.Y201H | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDK14 | c.40G>C p.G14R | Missense Mutation (SNP) | VAF 67/119 reads (56%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- DDIAS | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 18/448 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.357); called by muse, mutect2
- ENO4 | c.80A>C p.Y27S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPN2 | c.1233G>A p.W411* | Nonsense Mutation (SNP) | VAF 70/127 reads (55%) | called by muse, mutect2, varscan2
- FAM161B | c.1955C>T p.A652V (on ENST00000651776; = p.A589V on NM_152445.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- GLYCTK | c.377+3_377+20del p.X126_splice | Splice Site (DEL) | VAF 50/168 reads (30%) | called by mutect2, pindel, varscan2
- HTT | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | called by muse, varscan2
- KAT6A | c.3901G>A p.E1301K | Missense Mutation (SNP) | VAF 190/194 reads (98%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1109 | c.3861C>A p.S1287R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, varscan2
- LHPP | c.652G>C p.G218R | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- MIS18BP1 | c.2849G>A p.R950K | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2
- P3H4 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- PAH | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKCD | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB5C | c.166+1G>C p.X56_splice | Splice Site (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- SLC4A11 | c.1927A>G p.S643G | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TBX3 | c.1207C>G p.P403A (on ENST00000257566 / NM_016569.4; = p.P383A on NM_005996.4) | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TNXB | c.7813A>G p.I2605V (on ENST00000647633; = p.I2358V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.99); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TRAF3 | c.1247_1251del p.G416Afs*36 | Frame Shift Del (DEL) | VAF 64/72 reads (89%) | called by mutect2, pindel, varscan2
- USF3 | c.6109A>G p.I2037V | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- XBP1 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF729 | c.547A>G p.I183V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- ADGRA2 | c.825C>T p.N275= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs752343931, COSV100178443; called by muse, mutect2, varscan2
- CNTLN | c.2589C>T p.D863= | Silent (SNP) | VAF 58/114 reads (51%) | catalogued as rs201934878, COSV52088711; called by muse, mutect2, varscan2
- DDI1 | c.549G>A p.L183= | Silent (SNP) | VAF 66/158 reads (42%) | catalogued as rs1241982192; called by muse, mutect2, varscan2
- GPATCH1 | c.1404C>T p.N468= | Silent (SNP) | VAF 73/132 reads (55%) | catalogued as rs373378112; called by muse, mutect2, varscan2
- HPS3 | c.330G>A p.G110= | Silent (SNP) | VAF 10/222 reads (5%) | catalogued as rs1391143224; called by muse, mutect2
- IGHM | c.66C>T p.S22= | Silent (SNP) | VAF 124/124 reads (100%) | called by muse, mutect2, varscan2
- KLF4 | c.768C>T p.D256= | Silent (SNP) | VAF 88/189 reads (47%) | called by muse, mutect2, varscan2
- MAGEC1 | c.1674C>T p.S558= | Silent (SNP) | VAF 64/64 reads (100%) | catalogued as rs1170520660; called by muse, mutect2, varscan2
- PXDN | c.1221C>T p.S407= | Silent (SNP) | VAF 45/171 reads (26%) | catalogued as rs1252644359, COSV53244457; called by muse, mutect2, varscan2
- THAP10 | c.243G>A p.L81= | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as rs773026515; called by muse, mutect2, varscan2
- VPS13A | c.4380T>C p.D1460= | Silent (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- VXN | c.567G>A p.R189= | Silent (SNP) | VAF 118/124 reads (95%) | called by muse, mutect2, varscan2
- ADGRE5 | c.772+21C>T | Intron (SNP) | VAF 68/94 reads (72%) | called by muse, mutect2, varscan2
- APBB3 | c.291-70G>A | Intron (SNP) | VAF 45/84 reads (54%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021657 G>A | 5'Flank (SNP) | VAF 21/40 reads (53%) | catalogued as rs1565932227; called by muse, mutect2, varscan2
- CCDC144A | c.665-710A>G | Intron (SNP) | VAF 30/59 reads (51%) | called by muse, mutect2, varscan2
- COG3 | c.*920T>G | 3'UTR (SNP) | VAF 15/15 reads (100%) | called by muse, mutect2, varscan2
- COMTD1 | c.636+134C>G | Intron (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- DENND2A | c.*177G>A | 3'UTR (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- DGKI | c.*348T>C | 3'UTR (SNP) | VAF 42/125 reads (34%) | called by muse, mutect2, varscan2
- DMXL2 | c.*360C>T | 3'UTR (SNP) | VAF 31/79 reads (39%) | catalogued as rs543909290, COSV99196382; called by muse, mutect2, varscan2
- DPP9 | c.1945-85G>A | Intron (SNP) | VAF 58/178 reads (33%) | catalogued as rs370657372; called by muse, mutect2, varscan2
- DYNC2I1 | c.*27C>T | 3'UTR (SNP) | VAF 16/407 reads (4%) | called by muse, mutect2
- EFNA3 | c.*313G>C | 3'UTR (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- ELAVL4 | chr1:50201586 del T | 3'Flank (DEL) | VAF 4/34 reads (12%) | catalogued as rs1454258425; called by pindel, varscan2
- ELFN2 | c.*4138G>A | 3'UTR (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- ETF1 | c.*538T>A | 3'UTR (SNP) | VAF 64/110 reads (58%) | called by muse, mutect2, varscan2
- FAM102A | c.*1847T>C | 3'UTR (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- FLRT2 | c.*1128C>G | 3'UTR (SNP) | VAF 30/31 reads (97%) | called by muse, mutect2, varscan2
- GABRA6 | c.*364G>T | 3'UTR (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- GALNT17 | c.-595C>G | 5'UTR (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- GALNT5 | c.*2737T>G | 3'UTR (SNP) | VAF 40/93 reads (43%) | called by muse, mutect2, varscan2
- GFER | c.259-108A>G | Intron (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- GORAB | c.522-16A>C | Intron (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2, varscan2
- GRM7 | c.-84G>C | 5'UTR (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- HYDIN2 | n.12594T>C | RNA (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- ITGA2 | c.*932C>T | 3'UTR (SNP) | VAF 63/145 reads (43%) | called by muse, mutect2, varscan2
- ITPKA | c.*131G>C | 3'UTR (SNP) | VAF 12/54 reads (22%) | catalogued as rs879063303; called by muse, mutect2
- KLF12 | c.*3715G>A | 3'UTR (SNP) | VAF 40/41 reads (98%) | catalogued as COSV66579621; called by muse, mutect2, varscan2
- KLF12 | c.*9A>C | 3'UTR (SNP) | VAF 12/12 reads (100%) | called by muse, mutect2, varscan2
- LIMS2 | c.*514A>C | 3'UTR (SNP) | VAF 48/116 reads (41%) | called by muse, mutect2, varscan2
- MMS22L | c.*1447A>G | 3'UTR (SNP) | VAF 35/72 reads (49%) | catalogued as rs1369712399; called by muse, mutect2, varscan2
- MPIG6B | c.*68T>G | 3'UTR (SNP) | VAF 53/94 reads (56%) | called by muse, mutect2, varscan2
- NACA | c.71-2094A>G | Intron (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- NECTIN1 | c.*1857G>T | 3'UTR (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- NPAT | c.*1180T>G | 3'UTR (SNP) | VAF 54/100 reads (54%) | called by muse, mutect2, varscan2
- NRG3 | chr10:82986606 C>G | 3'Flank (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- NUDT4 | c.*2252del | 3'UTR (DEL) | VAF 105/1049 reads (10%) | called by mutect2, pindel, varscan2
- PIK3CA | c.*5316A>T | 3'UTR (SNP) | VAF 123/526 reads (23%) | called by muse, varscan2
- RAB3B | c.*11527G>T | 3'UTR (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- RAB3IP | c.*5787G>T | 3'UTR (SNP) | VAF 32/106 reads (30%) | called by muse, mutect2, varscan2
- RAP2B | c.*3105G>C | 3'UTR (SNP) | VAF 47/92 reads (51%) | called by muse, mutect2, varscan2
- RRP15 | c.*5556C>T | 3'UTR (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- SEL1L3 | c.3259+1079C>T | Intron (SNP) | VAF 3/44 reads (7%) | catalogued as rs910853912; called by muse, mutect2
- SERPINB12 | c.243+39G>A | Intron (SNP) | VAF 90/200 reads (45%) | called by muse, mutect2, varscan2
- ST8SIA2 | c.*1924_*1927del | 3'UTR (DEL) | VAF 24/58 reads (41%) | called by pindel, varscan2
- TMEM26 | c.*2425C>T | 3'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- TMPRSS11A | c.-525G>A | 5'UTR (SNP) | VAF 42/54 reads (78%) | called by muse, mutect2, varscan2
- TP53INP2 | c.*1685G>A | 3'UTR (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- TRAPPC13 | c.*779A>G | 3'UTR (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- USP47 | c.*1025T>C | 3'UTR (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- VPS35 | c.*1189A>G | 3'UTR (SNP) | VAF 76/151 reads (50%) | called by muse, mutect2, varscan2
- VSIG1 | c.*1439T>C | 3'UTR (SNP) | VAF 51/52 reads (98%) | called by muse, mutect2, varscan2
- WAC | c.274+70G>T | Intron (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- WDR55 | c.*1127G>A | 3'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- ZSWIM8 | c.2893+229G>A | Intron (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
